Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A9WI, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A9WI-01A (Primary Tumor).

PROSTATE AND PELVIC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA WITH DUCTAL COMPONENT

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN NOT PRESENT

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

NOT DETERMINED

TUMOR LOCATION

APEX

MID

BASE

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

SITE OF EXTRA-PROSTATIC EXTENSION

NON DETERMINED

SEMINAL VESICAL INVASION

ABSENT

SURGICAL MARGINS

FREE OF INVASIVE CARCINOMA

LYMPHOVASCULAR INVASION

ABSENT

PERINEURAL INVASION

ABSENT

TUMOR VOLUME

PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: 20%

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

RIGHT NODAL STATION

NUMBER OF NODES IDENTIFIED: 8

NUMBER OF NODES INVOLVED BY METASTASIS: 0

LEFT NODAL STATION

NUMBER OF NODES IDENTIFIED: 7

NUMBER OF NODES INVOLVED BY METASTASIS: 1

DIAMETER OF LARGEST LYMPH NODE METASTASIS: NOT DETERMINED

ADDITIONAL PATHOLOGIC FINDINGS

HIGH-GRADE PROSTATIC INTRA-EPITHELIAL NEOPLASIA

NODULAR HYPERPLASIA

PATHOLOGICAL STAGING

pT3a

pN1

pMX

ICD-O-3
Adenocarcinoma, NOS 8140/3
Adenocarcinoma w/ mixed
subtypes (acinar & ductal) 8255/3
Site Prostate NOS C61.9
9/5/19/14

Source: NCI Genomic Data Commons file 61e6e95e-5a51-4f54-813b-cf5c58606cf7 (TCGA-YL-A9WI.746DB832-C507-4FD6-8B8A-09E6268BACC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).